Somatic mutation profile of tumor specimen TCGA-P5-A730-01A (aliquot TCGA-P5-A730-01A-11D-A32B-08) from TCGA case TCGA-P5-A730, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 22.0 years (8,043 days).
Specimen TCGA-P5-A730-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6851cf27-15ef-4a48-a4a2-fd96733ff59a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A730-10A (Blood Derived Normal), aliquot TCGA-P5-A730-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/786413ec-bc65-411b-a255-923bacc19e8c

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Nonsense Mutation 4, Silent 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 25/61 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADAM15 | c.2375A>G p.N792S (on ENST00000356955 / NM_207197.3; = p.N767S on NM_207195.3) | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.99); catalogued as COSV99665125; called by muse, mutect2, varscan2
- ADGRV1 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV101316222; called by muse, mutect2, varscan2
- ARHGEF12 | c.3833G>A p.W1278* | Nonsense Mutation (SNP) | VAF 32/139 reads (23%) | catalogued as COSV100755064; called by muse, mutect2, varscan2
- BUD31 | c.224_225del p.Y75* | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs1255808949; called by mutect2, pindel, varscan2
- EAF2 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99877577; called by muse, mutect2, varscan2
- KIF18A | c.1293G>C p.Q431H | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.461); catalogued as COSV99588927; called by muse, mutect2
- MAK16 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV100789451; called by muse, mutect2, varscan2
- MARCHF8 | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100165926; called by muse, mutect2
- MCM7 | c.293T>G p.V98G | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100385057; called by muse, mutect2, varscan2
- MDFIC | c.635G>T p.C212F | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99995297; called by muse, mutect2, varscan2
- NDST3 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs377531754, COSV56618069; called by muse, mutect2, varscan2
- NIPBL | c.426T>A p.Y142* | Nonsense Mutation (SNP) | VAF 40/100 reads (40%) | catalogued as COSV99241655; called by muse, mutect2, varscan2
- NLRP10 | c.1817G>A p.S606N | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100149836, COSV60782607; called by muse, mutect2, varscan2
- PAX4 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58391733; called by muse, mutect2
- RAG1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as COSV100201031; called by muse, mutect2, varscan2
- ZADH2 | c.808G>C p.G270R | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764319655, COSV59268828; called by muse, mutect2, varscan2
- NRXN1 | c.1311T>C p.C437= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1355738212, COSV100456069; called by muse, mutect2
- OR2T11 | c.837G>A p.T279= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs774253846, COSV100424873, COSV58185304; called by muse, mutect2, varscan2
- DDX41 | c.*345G>A | 3'UTR (SNP) | VAF 93/237 reads (39%) | catalogued as rs144382614; called by muse, mutect2, varscan2
